Gene-level copy-number profile of tumor specimen TCGA-66-2769-01A from TCGA case TCGA-66-2769, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 75.3 years (27,515 days).
Specimen TCGA-66-2769-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.39f1d1e7-004e-4c27-bc80-7c5e083647e8.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-66-2769-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/32083a19-9be9-4312-95a2-adf91e2dfcaf

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 8; copy number 1: 1,198; copy number 2: 16,900; copy number 3: 21,408; copy number 4: 14,474; copy number 5: 857; copy number 6: 1,137; copy number 7: 1,079; copy number 8: 1,030; copy number 9: 663; copy number 10: 501; copy number 11: 21; copy number 12: 154; copy number 14: 268; copy number 15: 51; copy number 16: 11; copy number 26: 23; copy number 32: 10; copy number 51: 9; copy number 79: 12.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-66-2769-01A-02D-0844-01): tumor purity 0.32, ploidy 3.39, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 3,832 genes in 18 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:157,081,667–183,884,933, 380 genes, copy number 7 (within-gene range 5–7) (broad region; genes not listed).
- chr3:187,197,090–198,222,513, 241 genes, copy number 7 (broad region; genes not listed).
- chr4:51,843,000–55,636,698, 76 genes, copy number 12–79 (broad region; genes not listed).
- chr4:65,669,961–66,897,371, 11 genes, copy number 15–32: EPHA5-AS1, AC104137.1, RNU2-40P, AC097110.1, AC116049.1, AC096721.1, IFITM3P1, AC110809.1, MIR1269A, RPS23P3, RNU6-699P.
- chr5:58,198–45,895,970, 710 genes, copy number 8 (broad region; genes not listed).
- chr8:37,668,898–38,973,912, 50 genes, copy number 15 (within-gene range 6–15): RNU6-607P, ZNF703, AC138356.3, AC138356.1, ERLIN2, AC138356.2, PLPBP, ADGRA2, BRF2, RAB11FIP1, AC130304.1, RN7SL709P, GOT1L1, AC144573.1, ADRB3, RPL12P48, EIF4EBP1, AP006545.1, AP006545.3, AP006545.2, ASH2L, RNU6-988P, AC084024.1, STAR, AC084024.3, LSM1, RNU6-323P, BAG4, AC084024.2, AC084024.4, DDHD2, PLPP5, NSD3, AC087362.2, AC087362.1, AC087623.2, LETM2, FGFR1, AC087623.3, AC087623.1, RPS20P22, C8orf86, AC069120.1, RNF5P1, AC016813.1, TACC1, Y_RNA, AC067817.1, AC067817.2, PLEKHA2.
- chr8:46,549,089–49,554,414, 67 genes, copy number 8 (broad region; genes not listed).
- chr8:53,966,552–145,066,685, 1,420 genes, copy number 7–10 (broad region; genes not listed).
- chr12:1,380,060–2,004,535, 16 genes, copy number 11: AC004672.1, AC004672.2, LINC00942, WNT5B, FBXL14, MIR3649, ADIPOR2, AC005183.1, AC005343.4, RPS4XP14, CACNA2D4, AC005343.7, LRTM2, AC005342.2, LINC00940, DCP1B.
- chr12:2,004,666–2,223,479, 5 genes, copy number 11: AC005342.1, CACNA1C-IT1, CACNA1C-IT2, AC005344.1, CACNA1C-AS4.
- chr12:2,695,765–2,812,902, 1 gene, copy number 12 (within-gene range 1–12): ITFG2-AS1.
- chr12:2,752,597–10,572,688, 334 genes, copy number 8–12 (broad region; genes not listed).
- chr12:17,479,446–19,376,400, 19 genes, copy number 12 (within-gene range 5–12): AC048352.1, LINC02378, MIR3974, Y_RNA, RERGL, PIK3C2G, NDFIP1P1, AC092851.1, ZKSCAN7P1, PLCZ1, PSMC1P9, AC087242.1, CAPZA3, RPL7P6, MEF2BNBP1, PLEKHA5, AC092828.1, RN7SL459P, RN7SL67P.
- chr12:21,264,600–22,690,665, 30 genes, copy number 8 (within-gene range 5–8): SLCO1A2, IAPP, PYROXD1, ELOCP31, RECQL, GOLT1B, SPX, GYS2, AC010197.2, LDHB, AC010197.1, AC010185.1, KCNJ8, ABCC9, AC008250.1, AC008250.2, AC092862.1, CMAS, ST8SIA1, AC007671.1, SULT6B2P, RNU1-149P, AC087318.1, AC053513.1, C2CD5, AC053513.2, LRRC34P1, AC087241.1, AC087241.2, ETNK1.
- chr12:22,722,229–22,743,091, 2 genes, copy number 8: RPS27P22, AC084819.1.
- chr12:23,529,504–31,591,136, 152 genes, copy number 9 (within-gene range 3–9) (broad region; genes not listed).
- chr20:24,931,840–26,251,546, 50 genes, copy number 7: AL035661.1, CST7, APMAP, RNU6-1257P, AL035661.2, ACSS1, AL080312.2, VSX1, AL080312.1, AL035252.2, AL035252.1, AL035252.5, ENTPD6, Y_RNA, AL035252.4, AL035252.3, AL121772.1, PYGB, AL121772.2, AL121772.3, ABHD12, PPIAP2, GINS1, NINL, RNU6ATAC17P, NANP, ZNF337-AS1, RN7SL594P, MED28P7, ZNF337, AL031673.1, AL390198.1, VN1R108P, FAM182B, BSNDP1, AL390198.2, BSNDP2, CFTRP1, LINC01733, FAM182A, AL078587.1, AL078587.2, AL450124.1, BSNDP3, NCOR1P1, AL391119.1, AL121904.2, MIR663AHG, AL121904.1, MIR663A.
- chr21:10,328,411–30,097,836, 268 genes, copy number 14 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 822. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
